Somatic mutation profile of tumor specimen MP2PRT-PARLMM-TMP1-A (aliquot MP2PRT-PARLMM-TMP1-A-1-0-D-A83C-36) from MP2PRT case MP2PRT-PARLMM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,297 days).
Specimen MP2PRT-PARLMM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 168cc285-7faa-44a1-bc86-0a08de1c7eb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARLMM-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARLMM-NM1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1796b948-3299-4e92-a19c-d744449eaa5e

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 210/507 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FMN2 | c.3178G>A p.G1060R | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs559871488, COSV100146512; called by muse, varscan2
- SETD2 | c.2342C>T p.T781M | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1313153861, COSV100340326; called by muse, mutect2, varscan2
- IGHV4-59 | c.347_348insCCTAA p.R116Sfs*? | Frame Shift Ins (INS) | VAF 14/124 reads (11%) | called by pindel, varscan2
- POLDIP3 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 112/299 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- VCPIP1 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 125/268 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ADCY2 | c.714T>A p.R238= | Silent (SNP) | VAF 63/181 reads (35%) | called by muse, mutect2, varscan2
- MC1R | c.273C>T p.N91= | Silent (SNP) | VAF 221/581 reads (38%) | catalogued as rs371022090; called by muse, mutect2, varscan2
- ABCC9 | chr12:21801159 G>A | 3'Flank (SNP) | VAF 67/193 reads (35%) | catalogued as rs554811993, COSV53973652; ClinVar: not provided; called by muse, mutect2, varscan2
